Somatic mutation profile of tumor specimen TCGA-FV-A3R2-01A (aliquot TCGA-FV-A3R2-01A-11D-A22F-10) from TCGA case TCGA-FV-A3R2, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Age at diagnosis: 75.4 years (27,530 days).
Specimen TCGA-FV-A3R2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5152562-0fc0-49bb-b989-426771d0f167.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FV-A3R2-11A (Solid Tissue Normal), aliquot TCGA-FV-A3R2-11A-11D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0cdfe09-78b8-48b0-bea1-4175f4053038

The open-access MAF lists 95 somatic variants for this specimen: 65 protein-altering or splice-affecting, 23 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 23, Nonsense Mutation 7, Intron 5, Frame Shift Del 4, Splice Site 3, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908595, CM061104, COSV61068710; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 21/38 reads (55%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3485G>A p.R1162H | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV65887428; called by muse, mutect2, varscan2
- ADCY6 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV57168669, COSV57169583; called by muse, mutect2, varscan2
- ALOX12B | c.650+1G>T p.X217_splice | Splice Site (SNP) | VAF 38/58 reads (66%) | catalogued as COSV59873733; called by muse, mutect2, varscan2
- ANGPT1 | c.582A>T p.L194F | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV52445042; called by muse, mutect2, varscan2
- ANKMY1 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56036238; called by muse, mutect2, varscan2
- ANO4 | c.2864C>A p.P955Q (on ENST00000392977 / NM_001286615.2; = p.P920Q on NM_178826.4) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54600642; called by muse, mutect2, varscan2
- ARHGAP36 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 58/76 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52268318, COSV52271824; called by muse, mutect2, varscan2
- ATP10B | c.2951C>A p.S984Y | Missense Mutation (SNP) | VAF 158/288 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV59155766; called by muse, mutect2, varscan2
- AXIN1 | c.1020-1G>T p.X340_splice | Splice Site (SNP) | VAF 11/23 reads (48%) | catalogued as COSV51988941, COSV51990369; called by muse, mutect2, varscan2
- CACNA1A | c.3884T>C p.M1295T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64201396; called by muse, mutect2, varscan2
- CACNB4 | c.1420T>A p.L474M | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as COSV52396400; called by muse, mutect2, varscan2
- CDH9 | c.1501A>G p.K501E | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV50309763; called by muse, mutect2, varscan2
- CHD3 | c.5039G>T p.G1680V (on ENST00000330494 / NM_001005273.3; = p.G1646V on NM_005852.4) | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1298854987, COSV57876709; called by muse, mutect2, varscan2
- CHRNA3 | c.1336C>A p.Q446K | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV58775980, COSV58777247; called by muse, mutect2, varscan2
- DTNA | c.1257C>A p.N419K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1396259577, COSV52009227; called by muse, mutect2, varscan2
- FANK1 | c.776G>T p.R259M | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV64131429; called by muse, mutect2, varscan2
- FOXRED1 | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV55007372; called by muse, mutect2, varscan2
- GLIS3 | c.1519-1G>C p.X507_splice | Splice Site (SNP) | VAF 23/89 reads (26%) | catalogued as COSV60931056; called by muse, mutect2, varscan2
- GMNN | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); catalogued as COSV57777091; called by muse, mutect2, varscan2
- GSTZ1 | c.494G>T p.C165F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.376); catalogued as COSV53623794; called by muse, mutect2, varscan2
- HNRNPA1 | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.468); catalogued as COSV52937332; called by muse, mutect2, varscan2
- HSPA1L | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65149172; called by muse, mutect2, varscan2
- ICE2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55031930, COSV55031972; called by muse, mutect2, varscan2
- IFITM5 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs765481203, COSV66888144, COSV66888277; called by muse, mutect2, varscan2
- KSR2 | c.307A>T p.K103* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV60382275; called by muse, mutect2, varscan2
- LGR4 | c.2734G>T p.E912* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV58726252; called by muse, mutect2, varscan2
- LRP1B | c.3736G>T p.D1246Y | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs778648870, COSV67213111, COSV67236997; called by muse, mutect2, varscan2
- MAGEE1 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 37/49 reads (76%) | catalogued as COSV63910532; called by muse, mutect2, varscan2
- MAPK1 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53187157; called by muse, mutect2, varscan2
- MB21D2 | c.861G>A p.W287* | Nonsense Mutation (SNP) | VAF 46/77 reads (60%) | catalogued as COSV66664204; called by muse, mutect2, varscan2
- MPP1 | c.1259A>G p.E420G | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV65729767; called by muse, mutect2, varscan2
- MUC16 | c.30191C>A p.T10064K | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as COSV67475087; called by muse, mutect2, varscan2
- NKAPD1 | c.648A>C p.K216N (on ENST00000280352 / NM_001082970.2; = p.K217N on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.491); catalogued as COSV54777357, COSV54778755; called by muse, mutect2, varscan2
- ODF4 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 26/39 reads (67%) | catalogued as COSV60272327; called by muse, mutect2, varscan2
- OR10G8 | c.619T>C p.S207P | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV70908512, COSV70908735; called by muse, mutect2, varscan2
- OR12D2 | c.434C>A p.T145K | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV65828560; called by muse, mutect2, varscan2
- OR2T11 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1287482326, COSV58185154, COSV58186177; called by muse, mutect2, varscan2
- P2RX6 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as COSV60384596; called by muse, mutect2, varscan2
- PEX14 | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63061898; called by muse, mutect2, varscan2
- PI15 | c.706T>A p.Y236N | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52642406; called by muse, mutect2, varscan2
- POTEC | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 89/217 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV62803081, COSV62803083; called by muse, mutect2, varscan2
- PPP1R3A | c.1862G>A p.R621K | Missense Mutation (SNP) | VAF 158/301 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52885310, COSV52886773; called by muse, mutect2, varscan2
- PRPF8 | c.2035T>A p.S679T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.868); catalogued as COSV59264533; called by muse, mutect2, varscan2
- RFTN2 | c.1302C>A p.D434E | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.51); catalogued as COSV54389618; called by muse, mutect2, varscan2
- RPL10L | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.814); catalogued as COSV53560329; called by muse, mutect2, varscan2
- RTL9 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV71825790; called by muse, mutect2, varscan2
- SATB1 | c.85A>C p.K29Q | Missense Mutation (SNP) | VAF 93/160 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58670431; called by muse, mutect2, varscan2
- SPTBN1 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs1467998194, COSV61689753; called by muse, mutect2, varscan2
- STING1 | c.985G>T p.V329F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs748947114, COSV58172876; called by muse, mutect2, varscan2
- TCF4 | c.1351G>A p.V451M | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV61899497; called by muse, mutect2, varscan2
- TMPRSS11B | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 62/199 reads (31%) | catalogued as COSV60292914; called by muse, mutect2, varscan2
- TSC1 | c.1066del p.T356Pfs*84 | Frame Shift Del (DEL) | VAF 26/56 reads (46%) | catalogued as COSV53768447; called by mutect2, pindel, varscan2
- TYW1 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV55887968; called by muse, mutect2, varscan2
- UNC13D | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs766863447, COSV52885436; called by muse, mutect2, varscan2
- USP9Y | c.7176G>A p.M2392I | Missense Mutation (SNP) | VAF 67/84 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as COSV59099715; called by muse, varscan2
- USP9Y | c.7177G>T p.V2393L | Missense Mutation (SNP) | VAF 66/83 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV59099720; called by muse, varscan2
- WNT2 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 91/340 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55411823; called by muse, mutect2, varscan2
- ZPLD1 | c.56C>T p.A19V (on ENST00000466937 / NM_001329788.1; = p.A35V on NM_175056.2) | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs1222159125, COSV60354409; called by muse, mutect2, varscan2
- DNAH11 | c.13248_13257del p.E4416Dfs*67 | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | called by pindel, varscan2*
- EFCAB8 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- IGKV2-28 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 80/335 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, varscan2
- KIF14 | c.721del p.Q241Rfs*33 | Frame Shift Del (DEL) | VAF 48/143 reads (34%) | called by mutect2, pindel, varscan2
- SHANK1 | c.5691_5697del p.S1898Efs*233 | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | called by mutect2, pindel, varscan2
- ADIPOR1 | c.441G>T p.L147= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as COSV61851785; called by muse, varscan2
- BMPER | c.1197G>T p.S399= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV51822468, COSV51826062; called by muse, mutect2, varscan2
- BTBD7 | c.1707C>A p.I569= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV58287906; called by muse, mutect2, varscan2
- CTSL | c.183G>A p.L61= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV58246504; called by muse, mutect2, varscan2
- DAGLA | c.1062C>A p.I354= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV57197303, COSV99944527; called by muse, mutect2, varscan2
- FER1L6 | c.2928C>G p.T976= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV67550504, COSV67550810; called by muse, mutect2, varscan2
- GARRE1 | c.627C>T p.G209= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs772182883, COSV55100709; called by muse, mutect2, varscan2
- GOSR2 | c.288T>G p.T96= (on ENST00000393456 / NM_001321134.1; = p.T161= on NM_004287.5) | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV56662924; called by muse, mutect2
- IP6K3 | c.1023C>T p.G341= | Silent (SNP) | VAF 41/159 reads (26%) | catalogued as rs1175116858, COSV53390696; called by muse, mutect2, varscan2
- KCNH2 | c.3186T>A p.T1062= | Silent (SNP) | VAF 44/158 reads (28%) | catalogued as COSV51193168; called by muse, mutect2, varscan2
- LGR6 | c.681C>A p.T227= (on ENST00000367278 / NM_001017403.1; = p.T175= on NM_021636.3) | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV55159644; called by muse, mutect2, varscan2
- LNX1 | c.711G>C p.G237= (on ENST00000263925 / NM_001126328.3; = p.G141= on NM_032622.2) | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as COSV55784806, COSV55787374; called by muse, mutect2, varscan2
- MRPL1 | c.447A>G p.P149= | Silent (SNP) | VAF 52/122 reads (43%) | catalogued as COSV59675358; called by muse, mutect2, varscan2
- NETO1 | c.1086C>T p.I362= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs145217972, COSV100199688; called by muse, mutect2, varscan2
- NUP62 | c.1146G>T p.V382= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV61312508; called by muse, mutect2, varscan2
- PRDM16 | c.1644C>T p.P548= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- ROBO4 | c.372C>A p.V124= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV60625258; called by muse, mutect2
- SKP1 | c.396T>G p.P132= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV60435945; called by muse, mutect2, varscan2
- SLFN14 | c.138C>A p.I46= | Silent (SNP) | VAF 59/146 reads (40%) | catalogued as rs1243556594, COSV70570381; called by muse, mutect2, varscan2
- TMEM88 | c.99C>T p.A33= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV54683162; called by muse, mutect2, varscan2
- VCAN | c.8133T>A p.A2711= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV54108253; called by muse, mutect2, varscan2
- ZNF410 | c.294G>A p.P98= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as rs150263864; called by muse, mutect2, varscan2
- ZNF618 | c.39C>T p.D13= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as rs754153795, COSV55923540; called by mutect2, varscan2
- BACE2 | c.312+14518A>C | Intron (SNP) | VAF 32/101 reads (32%) | called by mutect2, varscan2
- BPIFA3 | c.*10A>C | 3'UTR (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100966985; called by muse, mutect2, varscan2
- CRABP1 | c.249+119T>C | Intron (SNP) | VAF 16/47 reads (34%) | catalogued as rs1192511283; called by muse, mutect2, varscan2
- EIF4G1 | c.631-12T>A | Intron (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- ENY2 | c.6+27C>A | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- TMEM215 | c.*3869del | 3'UTR (DEL) | VAF 27/90 reads (30%) | called by mutect2, pindel, varscan2
- TNNI2 | c.16-140T>G | Intron (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
